Surgical pathology report (de-identified scan), TCGA case TCGA-DU-A76K, project TCGA-LGG (Brain Lower Grade Glioma), tissue source site Henry Ford Hospital, specimen TCGA-DU-A76K-01A (Primary Tumor).

Anatomic Pathology/Cytology Document State: (version)
Update Date/Time:
Final 1

Patient Name: MRN:
DOB/Age/Gender: Male Provider:
Location: Responsible Staff:

Service Date/Time:

PATH.NO:

NAME:

AGE/SEX: M DOB:

MED. REC. NO:

SURGERY DATE:

RECEIVE DATE:

PHYSICIAN:

COPY TO:

PATHOLOGICAL DIAGNOSIS:

BRAIN BIOPSY, RIGHT PARIETO-OCCIPITAL LOBE: OLIGODENDROGLIOMA.
(MIB-1 = 6%)

Operation/Specimen: Rt. parietal occipital tumor.

Clinical History and Pre-Op Dx: None provided.

GROSS PATHOLOGY:

A. A 1.2 x 0.6 cm tissue fragment. Frozen section diagnosis:
Glioma, in #1 and #2.

B.

SPECIMEN: Right parietal/occipital.

FIXATIVE: None.

GENERAL: Fragments of focally hemorrhagic, gray-white soft brain
parenchyma 1.5 x 1.2 x 1 cm. in aggregate.

SECTIONS: X1.X2 - all.

MICROSCOPIC: Sections reveal a hypercellular oligodendroglioma
involving both the cortex and the white matter. The tumor shows areas
of prominent nuclear pleomorphism and hyperchromasia, but mitotic
figures are rare. Focal areas of endothelial hyperplasia are seen.
Necrosis is not identified. Clusters of calcification are noted. The
tumor is classified as grade B. MIB-1 stain shows the labelling index
of tumor cells is about 6%.

TISSUE COMMITTEE CODE: TC1.

BILLING CODES:

ICD 0-3
Oligodendroglioma, grade II
9450.3
Site Brain, supratentorial NOS
C71.0
path
Overlapping lesion of brain
(occipital + parietal lobes) C71.8
9/30/13

Source: NCI Genomic Data Commons file b0641bfc-3f55-4ddc-bc73-af74316408a7 (TCGA-DU-A76K.E30A6271-8007-4457-A48E-87EFAD8871D0.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).